CCDI case PBCELM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/862b427b-211b-402f-b6f3-38fc2fc69abd

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Overlapping lesion of nasopharynx; Age at diagnosis: 6.0 years (2,205 days).

Biospecimens (3 samples)
- Sample 0DQC1U: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQC21: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQC25: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
